CCDI case PBCPFZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e8d5600c-4e25-4c3d-bd2e-721a4c6c7134

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,426 days).

Biospecimens (3 samples)
- Sample 0DWTAA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWTBK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWTC0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
